CGCI case HTMCP-03-06-02424 — HIV+ Tumor Molecular Characterization Project - Cervical Cancer (CGCI-HTMCP-CC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/56a1f1ce-d1fc-49cd-9935-3185236931fa

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 35 years; Vital status: Dead; Days to death: 92 days.

Diagnoses (1)
1. Squamous cell carcinoma, keratinizing, NOS: ICD-O-3 morphology code: 8071/3; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 35.8 years (13,085 days); Year of diagnosis: 2016; Method of diagnosis: Biopsy; AJCC clinical T: T3b; AJCC clinical N: NX; AJCC clinical M: MX; FIGO stage: Stage IIIB; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 92 days.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 92 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day -8.

Other clinical attributes
- Day 0: Weight: 56 kg; Height: 165 cm; BMI: 20.6; CD4 count: 200; Haart treatment indicator: Yes; HIV viral load: 34; Hormonal contraceptive use: Former User; Hysterectomy type: Not Performed; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Day 0: Nadir CD4 count: 200.
- Day 0: Pregnancy outcome: Miscarriage.
- Comorbidities: HIV/AIDS.
- Risk factors: HIV/AIDS.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-03-06-02424-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-03-06-02424-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-03-06-02424-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 4; Pregnancies count miscarriage: 1; Total pregnancy count: 5; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Squamous Cell Carcinoma, Keratinizing; Keratinization squamous cell: Keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Hysterectomy Performed Ind-3: No; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: HIV status: Positive; Year of HIV diagnosis: 2011; Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes.
